Surgical pathology report (de-identified scan), TCGA case TCGA-FF-8061, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site SingHealth, specimen TCGA-FF-8061-01A (Primary Tumor).

Histopathology Report

Biosis No.

Final

Received Date/Time		Final
Reporting Information	Date/Time : Histopathologist : Laboratory :	Final
Consultant-In-Charge		Final
Submitting Physician		Final
Histopathology Report		Final

DIAGNOSIS

Small intestine and sigmoid colon: Diffuse large B-cell lymphoma.

Comment: The specimen shows lymphomatous involvement by diffuse large B-cell lymphoma. The phenotype is in keeping with germinal centre B-cell (GCB) type by Hans' criteria although the expression of FoxP1 and weak immunostaining for LMO2 has been reported in the activated B-cell (ABC) subtype.

GROSS DESCRIPTION

The specimen is received in formalin, labelled with patient's data, and designated "small bowel tumour with sigmoid colon". It consists of an enblock resection of small bowel tumour mass together with adherent segments of small and large bowel. The small bowel loops are twisted and kinked, with part of them entrapped within the encircling tumour mass, measuring in total approximately 70cm in length and 8cm in diameter. The tumour mass measures 15 x 14 x 9cm, located 7cm from far end and 4cm from near end of the small bowel. It has a fish-flesh pale pink appearance on cut sections. The large bowel is attached to the external surface of the tumour mass, measuring 9cm in length and 4.5cm in circumference. The mucosa of the bowel appears unremarkable. The external surface of the tumour is inked blue. Also received a piece of cross stapled bowel measuring 6 x 3.5 x 1cm. No discrete lesions are seen. No definite lymph nodes are identified in this specimen.
(A1-far margin of small bowel, A2-near margin of small bowel, A3&A4-shaved margins of large bowel, A5 to A8-tumour with entrapped small bowel, A9&A10-tumour with adjacent mucosa)

MICROSCOPIC DESCRIPTION

Sections show a transmural lymphomatous infiltrate in the small intestine, featuring a diffuse infiltrate of large lymphoid cells with scattered tingible body macrophages, imparting a focally 'starry sky' appearance. Neoplastic cells display vesicular chromatin, moderate nuclear pleomorphism, prominent nucleoli and scattered mitoses. Immunohistochemistry confirms the neoplastic lymphoid cells to be of B-cell lineage with expression of CD20 and PAX5. They co-express germinal centre markers CD10, bcl6 and heterogeneous staining for LMO2. At the same time there is also weak and heterogeneous expression of MUM1, as well as strong immunoreactivity for FoxP1. No residual follicular dendritic meshworks are seen with immunostaining for CD21. The proliferation fraction is high at >90% and there is strong expression of the anti-apoptotic molecule bcl2 in most tumour cells, thereby excluding Burkitt lymphoma. Immunohistochemical stains with CD20 and PAX5 demonstrate scattered small B lymphocytes and CD3 stains T lymphocytes. No marked expansion of these cells are seen.

Pathologist :

Source: NCI Genomic Data Commons file bf67ee96-666e-4fa0-bd2c-bc331567c88c (TCGA-FF-8061.9EA8BB70-9001-4BA3-8F3D-6B97AF99F875.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).